Somatic mutation profile of tumor specimen TCGA-G8-6906-01A (aliquot TCGA-G8-6906-01A-11D-2210-10) from TCGA case TCGA-G8-6906, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Intra-abdominal lymph nodes; Age at diagnosis: 58.2 years (21,272 days).
Specimen TCGA-G8-6906-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f822a55-cbe9-4a79-b96f-d6c17bcef20d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G8-6906-14A (Bone Marrow Normal), aliquot TCGA-G8-6906-14A-01D-2210-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f38fdd70-0ccb-43ad-b11a-45497bdfcf07

The open-access MAF lists 92 somatic variants for this specimen: 69 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 22, Nonsense Mutation 9, Frame Shift Del 3, Frame Shift Ins 2, In Frame Del 1, Splice Region 1, Splice Site 1, RNA 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 20/49 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 83/195 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1617A>T p.K539N (on ENST00000288602 / NM_001374244.1; = p.K499N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs397507476, CM080110, COSV56417995; called by muse, mutect2, varscan2
- C17orf97 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs111543298; called by muse, varscan2
- CDC37L1 | c.80A>C p.D27A | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.968); catalogued as rs758829078; called by muse, mutect2, varscan2
- CHRNA2 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.166); catalogued as rs548268816, COSV53556857, COSV53557723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJB8 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142768827; called by muse, mutect2, varscan2
- FIP1L1 | c.1594C>T p.R532* | Nonsense Mutation (SNP) | VAF 86/201 reads (43%) | catalogued as COSV55790573; called by muse, mutect2, varscan2
- GRID1 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1476036617; called by muse, mutect2, varscan2
- H4C4 | c.295T>G p.Y99D | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61591780; called by muse, mutect2, varscan2
- HERC1 | c.7217T>C p.M2406T | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1200117576; called by muse, mutect2, varscan2
- IGKV3-20 | c.148A>C p.S50R | Missense Mutation (SNP) | VAF 125/177 reads (71%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs375905796; called by muse, varscan2
- IGLV3-25 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as rs5751507; called by muse, mutect2, varscan2
- INPP5F | c.3223C>T p.R1075* | Nonsense Mutation (SNP) | VAF 54/107 reads (50%) | catalogued as rs780378505, COSV62820740; called by muse, mutect2, varscan2
- MICAL2 | c.3304G>A p.A1102T | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated, low confidence (0.46); PolyPhen possibly damaging (0.452); catalogued as rs148517207; called by muse, mutect2, varscan2
- MNX1 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs763110541; called by muse, varscan2
- NOTCH2 | c.7184C>G p.S2395* | Nonsense Mutation (SNP) | VAF 49/119 reads (41%) | catalogued as COSV104375150; called by muse, mutect2, varscan2
- OR5AK2 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.05); catalogued as rs955806114; called by muse, mutect2
- PLA2G5 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); catalogued as rs781327560; called by muse, mutect2, varscan2
- PLK1 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs34359215, COSV55622434; called by muse, mutect2, varscan2
- PLXNA4 | c.3668C>T p.P1223L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs760193383; called by muse, mutect2, varscan2
- POU2F2 | c.715A>G p.T239A (on ENST00000526816 / NM_001207025.3; = p.T223A on NM_002698.5) | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60759489, COSV60761129; called by muse, mutect2, varscan2
- RPL4 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs746341624; called by muse, mutect2, varscan2
- SEC16A | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.02); catalogued as rs371074782; called by muse, mutect2
- SLC4A1 | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167814744, CM951172; called by muse, mutect2, varscan2
- SLCO1C1 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV56879876; called by muse, mutect2, varscan2
- SPATA31D1 | c.245G>A p.W82* | Nonsense Mutation (SNP) | VAF 58/136 reads (43%) | catalogued as rs1441507735; called by muse, mutect2
- SSPOP | n.1910G>A | Splice Region (SNP) | VAF 36/100 reads (36%) | catalogued as rs1382933162, COSV50489134; called by muse, mutect2, varscan2
- SYT17 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.325); catalogued as rs201479500, COSV62547194; called by muse, mutect2, varscan2
- TMEM30A | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 39/52 reads (75%) | catalogued as rs1388813208, COSV57877097; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4105G>A p.G1369R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs754154860; called by muse, mutect2, varscan2
- TXNDC2 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV60155908; called by muse, mutect2, varscan2
- XKR3 | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.79); PolyPhen benign (0.049); catalogued as COSV58886981; called by muse, mutect2, varscan2
- ZC3HC1 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as rs777405892, COSV61298936; called by muse, mutect2, varscan2
- AMT | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.1518A>C p.E506D | Missense Mutation (SNP) | VAF 68/141 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ASXL3 | c.3688del p.L1230Ffs*26 | Frame Shift Del (DEL) | VAF 31/65 reads (48%) | called by mutect2, varscan2
- ASXL3 | c.3693del p.F1231Lfs*25 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | called by mutect2*, pindel, varscan2*
- BYSL | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C18orf25 | c.917T>A p.F306Y | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEBPZ | c.2461G>T p.V821F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFTR | c.54dup p.W19Lfs*26 | Frame Shift Ins (INS) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- CLRN3 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DEFA3 | c.128T>A p.V43E | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- DGKI | c.1646C>A p.A549E | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GNAI2 | c.814_816del p.K272del | In Frame Del (DEL) | VAF 20/155 reads (13%) | called by pindel, varscan2
- GOLGA4 | c.5223A>T p.L1741F | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GTPBP6 | c.1081C>T p.L361F | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHG2 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- INTS3 | c.2049G>T p.Q683H | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IRF8 | c.1274_1279del p.T425_*427delinsK | Nonstop Mutation (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel*, varscan2*
- KCNQ3 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- KMT2D | c.3157del p.S1053Pfs*3 | Frame Shift Del (DEL) | VAF 58/192 reads (30%) | called by pindel, varscan2
- LGALS3BP | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMO7 | c.573+2T>C p.X191_splice (on ENST00000357063; = p.X206_splice on NM_005358.5) | Splice Site (SNP) | VAF 24/93 reads (26%) | called by muse, mutect2, varscan2
- LRPAP1 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAP4K1 | c.729G>A p.W243* | Nonsense Mutation (SNP) | VAF 62/155 reads (40%) | called by muse, mutect2, varscan2
- MINDY2 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MORC4 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4D5 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 77/191 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PCOLCE | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PHF14 | c.2404dup p.R802Kfs*4 | Frame Shift Ins (INS) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- PLD2 | c.1783A>T p.T595S | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRN2 | c.2764T>C p.S922P | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.092); called by muse, mutect2
- RALGAPA2 | c.2527A>T p.K843* | Nonsense Mutation (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- TESC | c.226C>A p.P76T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM132D | c.376A>T p.N126Y | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNFRSF14 | c.608G>A p.W203* | Nonsense Mutation (SNP) | VAF 43/65 reads (66%) | called by muse, mutect2, varscan2
- TOP3A | c.1649A>T p.Y550F | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ABCG8 | c.513C>A p.A171= | Silent (SNP) | VAF 37/100 reads (37%) | called by muse, mutect2, varscan2
- ARC | c.1113G>A p.P371= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs371075422, COSV63077995; called by muse, mutect2, varscan2
- ASB17 | c.651G>A p.V217= | Silent (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- BTG1 | c.66C>T p.I22= | Silent (SNP) | VAF 8/161 reads (5%) | catalogued as rs1303289197, COSV55459359; called by muse, mutect2
- C3orf20 | c.1725G>A p.E575= | Silent (SNP) | VAF 45/138 reads (33%) | catalogued as rs774931901; called by muse, mutect2, varscan2
- CACHD1 | c.3084G>A p.L1028= | Silent (SNP) | VAF 63/158 reads (40%) | called by muse, mutect2, varscan2
- CAD | c.1206G>A p.G402= | Silent (SNP) | VAF 38/85 reads (45%) | called by muse, mutect2, varscan2
- CD163L1 | c.2274C>T p.G758= | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as COSV58024654; called by muse, mutect2, varscan2
- CDH8 | c.300A>G p.L100= | Silent (SNP) | VAF 40/101 reads (40%) | catalogued as rs368241476; called by muse, mutect2, varscan2
- CPB1 | c.988C>T p.L330= | Silent (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2, varscan2
- CRMP1 | c.1215G>A p.S405= | Silent (SNP) | VAF 71/169 reads (42%) | catalogued as rs1267349401, COSV61479821; called by muse, mutect2, varscan2
- ERCC6 | c.3462T>G p.S1154= | Silent (SNP) | VAF 56/147 reads (38%) | called by muse, mutect2, varscan2
- HTR1A | c.237G>A p.A79= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as rs1372481454, COSV60500412, COSV60502793; called by muse, mutect2, varscan2
- IGF2BP2 | c.96A>T p.G32= | Silent (SNP) | VAF 72/166 reads (43%) | called by muse, mutect2, varscan2
- IGHG2 | c.273C>T p.N91= | Silent (SNP) | VAF 77/225 reads (34%) | catalogued as rs1567186943; called by muse, mutect2
- KCNQ1 | c.1884C>T p.G628= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as rs769848998; ClinVar: likely benign; called by muse, mutect2, varscan2
- KLHL3 | c.966C>T p.F322= | Silent (SNP) | VAF 53/127 reads (42%) | catalogued as rs750511635; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPAP1 | c.2115T>C p.P705= | Silent (SNP) | VAF 107/259 reads (41%) | called by muse, mutect2, varscan2
- PARP4 | c.5097C>G p.A1699= | Silent (SNP) | VAF 73/299 reads (24%) | called by muse, mutect2, varscan2
- POTEF | c.3144G>A p.S1048= | Silent (SNP) | VAF 52/242 reads (21%) | catalogued as rs1186870232; called by muse, varscan2
- XIRP2 | c.6252T>G p.T2084= (on ENST00000628543; = p.T2259= on NM_152381.6) | Silent (SNP) | VAF 57/168 reads (34%) | called by muse, mutect2, varscan2
- ZNF570 | c.855G>A p.Q285= | Silent (SNP) | VAF 16/37 reads (43%) | called by muse, mutect2, varscan2
- FAM169B | n.798C>T | RNA (SNP) | VAF 49/110 reads (45%) | catalogued as rs1206391908, COSV60568690; called by muse, mutect2, varscan2
